Somatic mutation profile of tumor specimen TCGA-XF-AAML-01A (aliquot TCGA-XF-AAML-01A-11D-A42E-08) from TCGA case TCGA-XF-AAML, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 75.1 years (27,422 days).
Specimen TCGA-XF-AAML-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d961c0e1-19dd-4cff-aaf7-0eb0019c2ed9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-AAML-10A (Blood Derived Normal), aliquot TCGA-XF-AAML-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30668a78-56f1-46bc-b24b-b77619091078

The open-access MAF lists 557 somatic variants for this specimen: 398 protein-altering or splice-affecting, 144 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 338, Silent 144, Nonsense Mutation 40, Splice Site 11, Intron 7, 3'UTR 3, Frame Shift Del 3, Splice Region 3, RNA 3, Frame Shift Ins 2, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C3orf70 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 3/12 reads (25%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs757159118, COSV58586480, COSV58587413, COSV58588338; called by muse, mutect2
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 36/180 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- POLG | c.2480+1G>A p.X827_splice | Splice Site (SNP) | VAF 10/39 reads (26%) | catalogued as rs1567187326, CS083970, COSV51519560; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 18/45 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 18/60 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs397514495, CM056067, CM920671, CM942120, COSV52675795, COSV52676870, COSV52730435, COSV53567603; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AADACL3 | c.634C>A p.L212M | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as rs757247172, COSV60198141; called by muse, mutect2, varscan2
- ABCC10 | c.3957C>G p.L1319= (on ENST00000372530 / NM_001198934.2; = p.L1291= on NM_033450.2 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 7/18 reads (39%) | catalogued as COSV55084359; called by muse, mutect2, varscan2
- ABCC6 | c.4309G>A p.E1437K | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV52742154; called by muse, mutect2, varscan2
- ABCD3 | c.371G>C p.R124T | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV59865365; called by muse, mutect2, varscan2
- ABHD4 | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 10/51 reads (20%) | catalogued as rs748032634, COSV99360449; called by muse, mutect2, varscan2
- ACD | c.949G>C p.E317Q (on ENST00000620338; = p.E228Q on NM_022914.3) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV54665934; called by muse, mutect2, varscan2
- ACP5 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99520183; called by muse, mutect2
- ACSF2 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 3/29 reads (10%) | catalogued as COSV51972348; called by muse, mutect2
- ACSM3 | c.150C>A p.F50L | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.192); catalogued as COSV56843031; called by muse, mutect2, varscan2
- ADCY8 | c.1798G>T p.D600Y | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV53896579, COSV53904452, COSV53918783; called by muse, mutect2, varscan2
- ADGRE1 | c.1123-1G>C p.X375_splice | Splice Site (SNP) | VAF 8/28 reads (29%) | catalogued as COSV51672084; called by muse, mutect2, varscan2
- ADGRF5 | c.959C>T p.S320L | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.83); catalogued as rs767381721, COSV51929845; called by muse, mutect2, varscan2
- AGTPBP1 | c.2569-2A>G p.X857_splice (on ENST00000357081 / NM_001330701.2; = p.X817_splice on NM_015239.2) | Splice Site (SNP) | VAF 10/22 reads (45%) | catalogued as COSV61268607; called by muse, mutect2, varscan2
- AKAP6 | c.5783C>T p.S1928L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV55205105; called by muse, mutect2, varscan2
- AL592490.1 | c.1837G>C p.D613H | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69424521; called by muse, mutect2, varscan2
- ALKBH1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.101); catalogued as rs1445286642, COSV53173703; called by muse, mutect2, varscan2
- ALPK3 | c.2137G>A p.E713K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); catalogued as COSV51929420; called by muse, mutect2, varscan2
- ANXA3 | c.575C>T p.T192M | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs539172460, COSV53713158, COSV99363589; called by muse, mutect2, varscan2
- APOBEC3F | c.249G>C p.K83N | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV100415107; called by muse, mutect2, varscan2
- APPL1 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as COSV55699692; called by muse, mutect2
- ARHGAP32 | c.1485-1G>C p.X495_splice (on ENST00000310343 / NM_001378025.1; = p.X146_splice on NM_014715.4) | Splice Site (SNP) | VAF 9/26 reads (35%) | catalogued as COSV100086896; called by muse, mutect2
- ARID1A | c.6791C>A p.S2264* | Nonsense Mutation (SNP) | VAF 33/71 reads (46%) | catalogued as COSV61372401, COSV61380775, COSV61381424; called by muse, mutect2, varscan2
- ARID4A | c.2197G>C p.D733H | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.499); catalogued as COSV62161986; called by muse, mutect2, varscan2
- ARMC6 | c.577G>A p.D193N (on ENST00000392336; = p.D168N on NM_033415.4) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV99522922; called by muse, mutect2
- ARRDC3 | c.411G>A p.W137* | Nonsense Mutation (SNP) | VAF 21/73 reads (29%) | catalogued as COSV99475156; called by muse, mutect2, varscan2
- ART1 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.355); catalogued as rs748952979, COSV51702903; called by muse, mutect2, varscan2
- ARV1 | c.583C>A p.P195T | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV59617021; called by muse, mutect2, varscan2
- ASAP1 | c.929G>C p.G310A | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63044415; called by muse, mutect2, varscan2
- ASCC3 | c.6337G>A p.E2113K | Missense Mutation (SNP) | VAF 53/205 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201205349, COSV64972258; called by muse, mutect2, varscan2
- ASCC3 | c.4396C>A p.L1466I | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as COSV64972261; called by muse, mutect2, varscan2
- ASH1L | c.7207G>A p.D2403N (on ENST00000368346 / NM_001366177.2; = p.D2398N on NM_018489.3) | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); catalogued as COSV64205482; called by muse, varscan2
- ASH1L | c.3328C>T p.Q1110* | Nonsense Mutation (SNP) | VAF 25/61 reads (41%) | catalogued as COSV100853113; called by muse, mutect2, varscan2
- ASPG | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs370504843; called by muse, mutect2, varscan2
- ATM | c.2587G>A p.D863N | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV53726348, COSV53731519; called by muse, mutect2, varscan2
- ATP11B | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.98); PolyPhen benign (0.208); catalogued as COSV60026136; called by muse, mutect2, varscan2
- ATP11B | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); catalogued as COSV60026150; called by muse, mutect2, varscan2
- ATP1A1 | c.3032G>A p.R1011Q | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs758090295, COSV55189499; called by muse, mutect2, varscan2
- ATXN7 | c.1016G>C p.R339T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV55748131; called by muse, mutect2, varscan2
- AXIN2 | c.942G>A p.M314I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV100195910; called by muse, mutect2
- BICRAL | c.2663C>A p.S888Y | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.748); catalogued as COSV58403543; called by muse, mutect2, varscan2
- BLK | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52049506; called by muse, mutect2, varscan2
- BMERB1 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1264364861, COSV100252591; called by muse, mutect2, varscan2
- BOD1L1 | c.6914T>C p.M2305T | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs1323073597, COSV50006582; called by muse, mutect2, varscan2
- BRCA2 | c.7060C>G p.Q2354E | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as CM030793, COSV66447831, COSV66448202; called by muse, mutect2, varscan2
- C15orf39 | c.1510G>A p.D504N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.086); catalogued as COSV62295727; called by muse, mutect2, varscan2
- C1orf112 | c.835C>T p.L279F | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53676622; called by muse, mutect2, varscan2
- C1orf112 | c.2013T>A p.D671E | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.106); catalogued as COSV53676638; called by muse, mutect2, varscan2
- CACNB3 | c.598C>T p.L200F | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56397172; called by muse, varscan2
- CALM2 | c.27G>C p.Q9H | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV55398759; called by muse, mutect2, varscan2
- CALR3 | c.92-1G>A p.X31_splice | Splice Site (SNP) | VAF 13/65 reads (20%) | catalogued as rs373161457; called by muse, mutect2, varscan2
- CBFA2T3 | c.607G>C p.V203L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV51923221; called by muse, mutect2, varscan2
- CCDC191 | c.2637G>A p.W879* | Nonsense Mutation (SNP) | VAF 15/70 reads (21%) | catalogued as COSV99877910; called by muse, mutect2, varscan2
- CCDC88A | c.1522G>C p.E508Q | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1398205432, COSV55056330; called by muse, mutect2, varscan2
- CD109 | c.1654C>T p.Q552* | Nonsense Mutation (SNP) | VAF 3/27 reads (11%) | catalogued as COSV99752602; called by muse, mutect2
- CDC42BPA | c.4270C>G p.L1424V (on ENST00000334218 / NM_001366019.2; = p.L1411V on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62002343; called by muse, mutect2, varscan2
- CDH2 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV52271834, COSV99298758; called by muse, mutect2, varscan2
- CDS2 | c.1258C>T p.Q420* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as COSV100986064; called by muse, mutect2, varscan2
- CEBPZ | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.055); catalogued as COSV50016906; called by muse, mutect2, varscan2
- CEBPZ | c.539G>C p.G180A | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV50016910; called by muse, mutect2, varscan2
- CELSR3 | c.7649C>A p.S2550Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50840027; called by muse, mutect2, varscan2
- CFHR2 | c.695G>T p.R232I | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as rs1363062685, COSV66380465; called by muse, mutect2, varscan2
- CHAF1A | c.996G>C p.K332N | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV56670319, COSV56672381; called by muse, mutect2, varscan2
- CIITA | c.731C>G p.S244C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV60854069; called by muse, mutect2, varscan2
- CLCN6 | c.2185G>C p.D729H | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.123); catalogued as COSV56737889; called by muse, mutect2, varscan2
- CLEC2D | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.173); catalogued as rs1157708145, COSV51992556; called by muse, mutect2, varscan2
- CLPX | c.1693C>T p.R565W | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200158367; called by muse, mutect2, varscan2
- CLSTN2 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV71718180; called by muse, mutect2, varscan2
- CNTN2 | c.1852G>A p.D618N | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV59348166; called by muse, mutect2, varscan2
- CNTN2 | c.1853A>T p.D618V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV59348173; called by muse, mutect2, varscan2
- CNTNAP5 | c.47C>G p.S16C | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.751); catalogued as COSV70472977, COSV70492625; called by muse, mutect2, varscan2
- COCH | c.979G>A p.V327I (on ENST00000216361 / NM_001347720.1; = p.V262I on NM_004086.3) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as rs1359268072, COSV53549721; called by muse, varscan2
- COG8 | c.1441C>T p.R481C | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs778596903, COSV55340356; called by muse, mutect2, varscan2
- COL23A1 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.992); catalogued as rs1252736112, COSV66786224, COSV66789421; called by muse, mutect2, varscan2
- COL24A1 | c.4171G>A p.E1391K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV65301855, COSV65304485; called by muse, mutect2, varscan2
- COL9A1 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as rs778243284, COSV61828847; called by muse, mutect2
- COPE | c.60C>G p.F20L | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.427); catalogued as COSV53229460, COSV53232034; called by muse, mutect2, varscan2
- COX5A | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.061); catalogued as rs1016607099, COSV59279064; called by muse, mutect2, varscan2
- CPLANE2 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1289066461, COSV65056593; called by muse, mutect2, varscan2
- CR2 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV65506059, COSV65507475; called by muse, mutect2, varscan2
- CR2 | c.1226-1G>C p.X409_splice | Splice Site (SNP) | VAF 7/51 reads (14%) | catalogued as COSV100889530; called by muse, mutect2
- CRB1 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs190037839; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRTC3 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1309485555, COSV51594343; called by muse, mutect2, varscan2
- CRYL1 | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.038); catalogued as rs780602148, COSV53416316; called by muse, mutect2, varscan2
- CSMD3 | c.1166G>A p.R389K | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT tolerated (0.89); PolyPhen benign (0.007); catalogued as COSV52103961; called by muse, mutect2, varscan2
- CSMD3 | c.105G>A p.M35I | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV52103977, COSV52294512; called by muse, mutect2, varscan2
- CTC1 | c.3058C>T p.Q1020* | Nonsense Mutation (SNP) | VAF 16/79 reads (20%) | catalogued as COSV100236148; called by muse, mutect2, varscan2
- CTDSPL2 | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV52944786; called by muse, mutect2, varscan2
- CYP27B1 | c.1108C>G p.L370V | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV56983778; called by muse, mutect2, varscan2
- CYTIP | c.729G>C p.E243D | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs955122502, COSV51631973; called by muse, mutect2, varscan2
- DARS2 | c.1303G>T p.E435* | Nonsense Mutation (SNP) | VAF 5/43 reads (12%) | catalogued as COSV99508499; called by muse, mutect2, varscan2
- DCK | c.771G>C p.L257F | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.573); catalogued as rs1317411434, COSV54377584; called by muse, mutect2, varscan2
- DCUN1D4 | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100584351; called by muse, mutect2, varscan2
- DDX17 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.025); catalogued as COSV53246503; called by muse, mutect2, varscan2
- DDX20 | c.2311C>T p.Q771* | Nonsense Mutation (SNP) | VAF 16/76 reads (21%) | catalogued as COSV100861972; called by muse, mutect2, varscan2
- DDX60L | c.2915C>T p.S972L | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99486933; called by muse, mutect2
- DHRS7C | c.243G>C p.L81F | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57649647; called by muse, mutect2, varscan2
- DNAH7 | c.8926G>A p.D2976N | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56752074; called by muse, mutect2, varscan2
- DNAH8 | c.6800C>T p.S2267F | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59425324, COSV59484519; called by muse, mutect2, varscan2
- DNAJA4 | c.523C>G p.Q175E (on ENST00000343789; = p.Q204E on NM_018602.3) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.479); catalogued as COSV59424860; called by muse, mutect2, varscan2
- DNAJC18 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.53); catalogued as COSV57415077; called by muse, mutect2, varscan2
- DNM1L | c.1235C>T p.S412L | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV56772222; called by muse, mutect2, varscan2
- DNMBP | c.1448C>A p.S483Y | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.365); catalogued as COSV60620402; called by muse, mutect2, varscan2
- DPYD | c.1162C>G p.L388V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV64590851; called by muse, mutect2, varscan2
- DSP | c.4770G>C p.K1590N | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV65791185; called by muse, mutect2, varscan2
- EDIL3 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.309); catalogued as COSV56880244; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.042); catalogued as rs200344434, COSV62566682; called by muse, mutect2, varscan2
- EFEMP1 | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV62615024; called by muse, mutect2, varscan2
- EFHB | c.323G>A p.R108K | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.935); catalogued as COSV55544911; called by muse, mutect2, varscan2
- ELAPOR2 | c.1565C>T p.S522L (on ENST00000450689 / NM_001142749.3; = p.S355L on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as rs200295149; called by muse, mutect2, varscan2
- EMSY | c.1928C>G p.S643C | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.594); catalogued as COSV58257378; called by muse, mutect2, varscan2
- ENPEP | c.1145C>G p.S382* | Nonsense Mutation (SNP) | VAF 16/63 reads (25%) | catalogued as COSV99487073; called by muse, mutect2, varscan2
- ENPP5 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 67/388 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57908062; called by muse, mutect2, varscan2
- EPG5 | c.7321G>A p.E2441K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.295); catalogued as COSV56344632; called by muse, mutect2, varscan2
- ERBB3 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT tolerated (0.92); PolyPhen benign (0.139); catalogued as COSV57246759; called by muse, mutect2, varscan2
- F13B | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 67/139 reads (48%) | catalogued as COSV100803189; called by muse, mutect2, varscan2
- F7 | c.547G>C p.D183H | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as CM045575, CM090325, COSV60645014; called by muse, mutect2, varscan2
- FAM189B | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as rs1189935595, COSV56943638; called by muse, mutect2
- FAM214A | c.2861C>T p.S954L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV55922130; called by muse, mutect2, varscan2
- FAM43B | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.698); catalogued as rs1377013509, COSV100261458; called by muse, mutect2, varscan2
- FAM71A | c.1264G>C p.E422Q | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as rs1415505560, COSV54234628; called by muse, mutect2, varscan2
- FAM81B | c.225G>C p.K75N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.017); catalogued as rs375187381, COSV51980598; called by mutect2, varscan2
- FAT1 | c.8680G>A p.E2894K | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.622); catalogued as COSV71671959, COSV71676267; called by muse, mutect2, varscan2
- FAT1 | c.4070C>T p.S1357L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as rs1266940215, COSV71671961; called by muse, mutect2, varscan2
- FBXL4 | c.1249C>T p.Q417* | Nonsense Mutation (SNP) | VAF 8/59 reads (14%) | catalogued as COSV100013857; called by muse, mutect2, varscan2
- FCGR3B | c.201C>G p.I67M | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV54208890; called by muse, mutect2, varscan2
- FGF4 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs751257747, COSV51449397; called by muse, mutect2, varscan2
- FLT3 | c.2562G>T p.W854C | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54044070; called by muse, mutect2, varscan2
- FNBP4 | c.646G>C p.E216Q | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55446277, COSV55446535; called by muse, mutect2, varscan2
- FRMPD1 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV66699179; called by muse, mutect2, varscan2
- FZD10 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs555606586, COSV57472035; called by muse, mutect2, varscan2
- GABRA2 | c.370C>G p.P124A | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62911953; called by muse, mutect2, varscan2
- GAS2L2 | c.2164C>T p.Q722* | Nonsense Mutation (SNP) | VAF 25/108 reads (23%) | catalogued as rs782286070; called by muse, mutect2, varscan2
- GASK1B | c.176C>T p.S59F | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.733); catalogued as COSV56704520; called by muse, mutect2, varscan2
- GDF11 | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57689238; called by muse, mutect2, varscan2
- GIMAP1 | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56187112; called by muse, mutect2, varscan2
- GMIP | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV99179082; called by muse, mutect2
- GNA13 | c.363G>C p.K121N | Missense Mutation (SNP) | VAF 51/258 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV71474380, COSV71475028; called by muse, mutect2, varscan2
- GNPNAT1 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV53590869; called by muse, mutect2, varscan2
- GOLGA2 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV60791562; called by muse, varscan2
- GPD2 | c.1267G>C p.D423H | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV60090163; called by muse, mutect2, varscan2
- GPNMB | c.1355T>C p.L452P (on ENST00000381990 / NM_001005340.2; = p.L440P on NM_002510.3) | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51696901; called by muse, mutect2, varscan2
- GRIA4 | c.2629G>T p.D877Y | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56882257; called by muse, mutect2, varscan2
- GRID1 | c.1499C>T p.S500F | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60014258; called by muse, mutect2, varscan2
- GRIN2B | c.3278C>T p.P1093L | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as COSV74204791; called by muse, mutect2, varscan2
- GTF3C5 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV100565249; called by muse, mutect2
- HELB | c.307C>G p.Q103E | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.107); catalogued as COSV56072122; called by muse, mutect2, varscan2
- HEPHL1 | c.1600C>A p.P534T | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.31); PolyPhen benign (0.173); catalogued as COSV59889485, COSV59897318; called by muse, mutect2, varscan2
- HNF4G | c.-23-2A>T | Splice Site (SNP) | VAF 31/57 reads (54%) | catalogued as COSV62965819; called by muse, mutect2, varscan2
- HOXD10 | c.746-1G>C p.X249_splice | Splice Site (SNP) | VAF 13/28 reads (46%) | catalogued as COSV50890624; called by muse, mutect2, varscan2
- HRC | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as COSV53255255; called by muse, mutect2, varscan2
- HS3ST4 | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58801796; called by muse, mutect2, varscan2
- HSPA4L | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV99612533; called by muse, mutect2
- HTR1A | c.1133C>T p.P378L | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60499870; called by muse, mutect2, varscan2
- HTRA2 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1311236619, COSV51206138; called by muse, mutect2, varscan2
- HTT | c.3251C>G p.S1084* | Nonsense Mutation (SNP) | VAF 22/300 reads (7%) | catalogued as COSV100750423; called by muse, mutect2
- HYDIN | c.6853G>A p.E2285K | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.77); catalogued as rs376758579, COSV59264173; called by muse, mutect2, varscan2
- ICAM2 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 19/51 reads (37%) | catalogued as COSV99856811; called by muse, mutect2, varscan2
- INPP5F | c.1165G>T p.D389Y | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.414); catalogued as COSV62819667, COSV62820529; called by muse, mutect2, varscan2
- INSL3 | c.280C>G p.L94V | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.209); catalogued as COSV57952768; called by muse, mutect2, varscan2
- IQSEC1 | c.2587G>A p.E863K | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.931); catalogued as rs747210938, COSV56221241; called by muse, mutect2, varscan2
- ITGA10 | c.2705C>G p.S902C | Missense Mutation (SNP) | VAF 44/472 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as COSV65196032; called by muse, mutect2
- ITPR2 | c.552G>C p.L184F | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV67264693; called by muse, mutect2, varscan2
- KAT6A | c.4627C>G p.Q1543E | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55902670, COSV99705454; called by muse, mutect2, varscan2
- KCNC4 | c.119T>G p.I40S | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63925026; called by mutect2, varscan2
- KCNC4 | c.1849C>A p.Q617K | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV100873559, COSV63925565; called by muse, mutect2
- KCNRG | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as COSV100078142; called by muse, mutect2, varscan2
- KDM5A | c.3581C>G p.S1194* | Nonsense Mutation (SNP) | VAF 25/109 reads (23%) | catalogued as COSV101238607; called by muse, mutect2, varscan2
- KERA | c.767C>G p.S256* | Nonsense Mutation (SNP) | VAF 21/80 reads (26%) | catalogued as rs755988989, COSV57129949, COSV99899305; called by muse, mutect2, varscan2
- KHDRBS1 | c.647G>T p.G216V | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV56980676; called by muse, mutect2, varscan2
- KIAA0100 | c.6124G>A p.D2042N | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56380715; called by muse, mutect2, varscan2
- KIAA0319 | c.1992-1G>C p.X664_splice | Splice Site (SNP) | VAF 34/75 reads (45%) | catalogued as COSV65496316; called by muse, mutect2, varscan2
- KIAA0753 | c.1565G>A p.R522K | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV63816761; called by muse, mutect2, varscan2
- KIAA1109 | c.3689C>T p.S1230F | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV52662459; called by muse, mutect2, varscan2
- KLHDC2 | c.1040G>C p.R347T | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.035); catalogued as rs775365639, COSV53586565; called by muse, mutect2, varscan2
- KLHDC3 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.92); PolyPhen benign (0.122); catalogued as COSV55063569; called by muse, mutect2, varscan2
- KLHDC3 | c.1075G>T p.D359Y | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.424); catalogued as COSV55063576; called by muse, varscan2
- KRI1 | c.431G>A p.R144K | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV57263607; called by muse, mutect2
- KRT19 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs778850224, COSV54177959, COSV54180782; called by muse, mutect2, varscan2
- KRT6C | c.1375G>C p.D459H | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52876412; called by muse, mutect2, varscan2
- KRT71 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.166); catalogued as rs778601047, COSV57288926; called by muse, mutect2, varscan2
- LARP4 | c.1349G>A p.R450K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs1209037766, COSV53319902; called by muse, mutect2, varscan2
- LAX1 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.178); catalogued as COSV65848802; called by muse, mutect2, varscan2
- LPAR2 | c.39C>G p.I13M | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.074); catalogued as COSV52554218, COSV52558369; called by muse, mutect2, varscan2
- LUC7L3 | c.1197G>C p.Q399H | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.496); catalogued as rs1051499459, COSV53585667; called by muse, mutect2, varscan2
- LY75 | c.3388G>A p.E1130K | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as COSV55101965, COSV55108431; called by muse, mutect2, varscan2
- MACF1 | c.21587G>A p.R7196K (on ENST00000372915; = p.R5241K on NM_012090.5) | Missense Mutation (SNP) | VAF 17/40 reads (43%) | catalogued as COSV57106053, COSV99246158; called by muse, mutect2, varscan2
- MAP1A | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV100288083; called by muse, mutect2
- MAP3K13 | c.1351G>A p.D451N | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV53983725, COSV53985190; called by muse, mutect2, varscan2
- MAP3K21 | c.948C>G p.I316M | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64043367; called by muse, mutect2, varscan2
- MAP3K4 | c.4738C>T p.H1580Y | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1055701377, COSV62330159; called by muse, mutect2, varscan2
- MASTL | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV58757960; called by muse, mutect2, varscan2
- MCM3AP | c.2963A>G p.K988R | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV52436333; called by muse, mutect2, varscan2
- MCM9 | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60163382, COSV60164452; called by muse, mutect2, varscan2
- MCTP2 | c.1777C>A p.P593T | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59140793, COSV59141197; called by muse, mutect2, varscan2
- MED13 | c.1906G>C p.D636H | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV67261937; called by muse, mutect2, varscan2
- MEX3C | c.1427G>A p.G476E | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV68529580; called by muse, mutect2, varscan2
- MKKS | c.623G>A p.R208K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.111); catalogued as COSV61397999; called by muse, mutect2, varscan2
- MRPL44 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as COSV51312258; called by muse, mutect2, varscan2
- MRPS7 | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.216); catalogued as rs1356706335, COSV99821463; called by muse, mutect2
- MTMR12 | c.348G>C p.Q116H | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.063); catalogued as COSV53782505; called by muse, mutect2
- MXRA5 | c.2439G>C p.L813F | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as COSV54224037; called by muse, mutect2, varscan2
- MYH3 | c.476C>G p.S159C | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV56861000; called by muse, mutect2, varscan2
- MYL12B | c.431G>A p.R144K | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs368473981, COSV99410622; called by muse, mutect2, varscan2
- MYO10 | c.4696C>T p.Q1566* | Nonsense Mutation (SNP) | VAF 4/47 reads (9%) | catalogued as COSV99944709; called by muse, mutect2
- MYO5B | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV53211312; called by muse, mutect2, varscan2
- MYOCD | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV58497309; called by muse, mutect2, varscan2
- MYOT | c.1454G>A p.R485H | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.222); catalogued as rs878976149, COSV51794737; called by muse, mutect2, varscan2
- N4BP2 | c.3982G>A p.E1328K | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as COSV54698954; called by muse, mutect2, varscan2
- N6AMT1 | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 19/53 reads (36%) | catalogued as rs761729543, COSV58134310, COSV58134349; called by muse, mutect2, varscan2
- NAA16 | c.1751C>G p.S584* | Nonsense Mutation (SNP) | VAF 7/14 reads (50%) | catalogued as rs1273397058, COSV101038235; called by muse, mutect2
- NAALADL2 | c.262C>G p.Q88E | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.675); catalogued as COSV101435739, COSV70794384; called by muse, mutect2, varscan2
- NAXD | c.247C>G p.Q83E | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.018); catalogued as rs774360118, COSV59393554; called by muse, mutect2, varscan2
- NAXE | c.740C>G p.S247C | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV58039033; called by muse, mutect2, varscan2
- NELL2 | c.1480G>C p.D494H | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.977); catalogued as COSV61569125; called by muse, mutect2, varscan2
- NFXL1 | c.1856C>T p.S619F | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.332); catalogued as COSV61198019; called by muse, mutect2, varscan2
- NIM1K | c.907C>T p.R303* | Nonsense Mutation (SNP) | VAF 8/84 reads (10%) | catalogued as rs573735157, COSV100389912; called by muse, mutect2
- NOA1 | c.1231T>C p.S411P | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.378); catalogued as COSV51735906; called by muse, mutect2
- NOL10 | c.1996G>C p.E666Q | Missense Mutation (SNP) | VAF 85/216 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV62037806; called by muse, mutect2, varscan2
- NPAT | c.3254C>T p.S1085F | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV53715951; called by muse, mutect2, varscan2
- NPC1L1 | c.3522G>C p.M1174I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV99202600; called by muse, mutect2
- NRXN3 | c.1700C>A p.A567D (on ENST00000335750 / NM_001330195.2; = p.A194D on NM_004796.6) | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59714518; called by muse, mutect2, varscan2
- NSUN6 | c.573G>A p.L191= | Splice Region (SNP) | VAF 15/83 reads (18%) | catalogued as COSV66031794; called by muse, mutect2, varscan2
- NUP210L | c.4081G>C p.E1361Q | Missense Mutation (SNP) | VAF 42/197 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV55141608; called by muse, mutect2, varscan2
- OARD1 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV55107345; called by muse, mutect2, varscan2
- OBSCN | c.13825C>T p.H4609Y | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1016641725, COSV52740237; called by muse, mutect2, varscan2
- OR1G1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.628); catalogued as COSV61029639; called by muse, mutect2, varscan2
- OSBPL3 | c.1310C>G p.S437C | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57652711; called by muse, mutect2, varscan2
- OSBPL7 | c.2174C>G p.S725* | Nonsense Mutation (SNP) | VAF 16/92 reads (17%) | catalogued as COSV50107315, COSV99136528; called by muse, mutect2, varscan2
- OSGEP | c.546G>C p.Q182H | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52831323; called by muse, mutect2, varscan2
- P4HB | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs1213082849, COSV58939963; called by muse, mutect2, varscan2
- PAX7 | c.183G>C p.E61D | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV100946565, COSV64751395; called by muse, mutect2, varscan2
- PCDHA4 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.16); catalogued as rs1554124966, COSV63538887; called by muse, mutect2, varscan2
- PCDHB5 | c.1574C>A p.A525E | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.169); catalogued as rs150324444; called by muse, mutect2, varscan2
- PCDHGB3 | c.1967C>T p.A656V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs1227917364, COSV53899213; called by muse, mutect2, varscan2
- PCDHGC3 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.081); catalogued as COSV52743275; called by muse, mutect2, varscan2
- PCK1 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs893537181, COSV60126167, COSV60130942; called by muse, mutect2, varscan2
- PDE6B | c.1435G>A p.D479N | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as COSV55323881; called by muse, mutect2
- PDGFRA | c.1535G>A p.R512Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.997); catalogued as rs1174017872, COSV57264755; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIK3R4 | c.957A>G p.I319M | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as COSV63239105; called by muse, mutect2, varscan2
- PIP4K2B | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs768191198; called by muse, mutect2, varscan2
- PITHD1 | c.426-1G>A p.X142_splice | Splice Site (SNP) | VAF 12/26 reads (46%) | catalogued as rs1359128839, COSV55754418, COSV55754665; called by muse, mutect2, varscan2
- PLAT | c.453G>T p.W151C | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99534965; called by muse, mutect2
- PLK4 | c.1252G>C p.E418Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.059); catalogued as COSV54636337; called by muse, mutect2, varscan2
- POLR1A | c.3257G>A p.R1086K | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV55689157, COSV99808511; called by muse, mutect2, varscan2
- POLR3D | c.1064C>A p.S355Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60570491; called by muse, mutect2, varscan2
- PPARGC1A | c.1891C>T p.R631W | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs773200805, COSV53524484; called by muse, mutect2, varscan2
- PPP2R5C | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as COSV58268328; called by muse, mutect2, varscan2
- PRB2 | c.865C>T p.Q289* | Nonsense Mutation (SNP) | VAF 106/244 reads (43%) | catalogued as COSV101231367; called by muse, varscan2
- PRDM2 | c.3310G>A p.E1104K | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV52442894; called by muse, mutect2, varscan2
- PRH1 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs372677799; called by muse, mutect2, varscan2
- PRKDC | c.686C>A p.S229* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100038465; called by muse, mutect2, varscan2
- PRSS58 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs149180097, COSV73488438; called by muse, mutect2, varscan2
- PSIP1 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.054); catalogued as rs1171526472, COSV101050915, COSV66253623; called by muse, mutect2, varscan2
- PSMA8 | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV57601024; called by muse, mutect2, varscan2
- PSORS1C1 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as rs151153963, COSV52535031; called by muse, varscan2
- PTK7 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV57846411; called by muse, mutect2, varscan2
- PTPRM | c.2057G>A p.G686E | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV59844409; called by muse, mutect2, varscan2
- PTRH1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.191); catalogued as COSV58852062; called by muse, mutect2, varscan2
- PUM1 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 42/90 reads (47%) | catalogued as COSV99927486; called by muse, mutect2, varscan2
- RAB22A | c.37G>T p.D13Y | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54830118; called by muse, mutect2
- RAB40AL | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 37/47 reads (79%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.893); catalogued as COSV54433627; called by muse, mutect2, varscan2
- RAB5C | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60524139, COSV60524185; called by muse, varscan2
- RASAL2 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV62709618, COSV62713604; called by muse, mutect2, varscan2
- RB1 | c.928G>T p.G310* | Nonsense Mutation (SNP) | VAF 6/13 reads (46%) | catalogued as rs1214283717, CM030500, COSV57328359; called by muse, mutect2, varscan2
- RBM39 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV53613778, COSV99488424; called by muse, mutect2, varscan2
- REV3L | c.5185G>C p.E1729Q | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV62615019; called by muse, mutect2, varscan2
- REV3L | c.4962G>C p.Q1654H | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV62615029; called by muse, mutect2, varscan2
- REV3L | c.4760G>T p.R1587I | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV62615038; called by muse, mutect2, varscan2
- RGS21 | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as COSV69881550; called by muse, mutect2, varscan2
- RGS22 | c.3743C>G p.S1248C | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV62657387; called by muse, mutect2, varscan2
- RGS7BP | c.425C>G p.S142C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV61833475, COSV61835070; called by muse, mutect2, varscan2
- RHOH | c.378C>G p.H126Q | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0.163); catalogued as rs368622526; called by muse, mutect2, varscan2
- RHOT2 | c.1099C>T p.L367= | Splice Region (SNP) | VAF 26/51 reads (51%) | catalogued as rs200771890, COSV53466361; called by muse, mutect2, varscan2
- RNF213 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.048); catalogued as COSV60619000; called by muse, mutect2, varscan2
- RPH3A | c.213G>A p.M71I (on ENST00000389385 / NM_001143854.2; = p.M67I on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as COSV66989985; called by muse, mutect2, varscan2
- RPS6KA2 | c.1765G>C p.D589H | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55815665; called by muse, mutect2, varscan2
- RRM2B | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); catalogued as COSV52565338, COSV52565576; called by muse, mutect2, varscan2
- RTCA | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV53119346; called by muse, mutect2, varscan2
- SAP130 | c.2291C>T p.S764L | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.015); catalogued as rs1174263715, COSV52094302; called by muse, mutect2, varscan2
- SCN2A | c.3502G>A p.E1168K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.796); catalogued as COSV51832446; called by muse, mutect2, varscan2
- SEC11C | c.181A>G p.I61V | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.023); catalogued as COSV55310897; called by muse, mutect2, varscan2
- SEC24C | c.1228-2A>C p.X410_splice | Splice Site (SNP) | VAF 32/47 reads (68%) | catalogued as COSV59539832; called by muse, mutect2, varscan2
- SECISBP2 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV60527486, COSV60528240; called by muse, mutect2, varscan2
- SETD2 | c.6604C>G p.P2202A | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs143083979, COSV57431003, COSV57431948; called by muse, mutect2, varscan2
- SETD2 | c.4573C>G p.L1525V | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1277628559, COSV57430261; called by muse, mutect2, varscan2
- SGTB | c.128T>C p.F43S | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV66817287; called by muse, mutect2, varscan2
- SH3TC2 | c.3081C>G p.I1027M | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV60460756; called by muse, varscan2
- SHANK1 | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.763); catalogued as COSV53247504; called by muse, mutect2
- SHANK2 | c.2534G>A p.R845Q | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.49); catalogued as rs782015001, COSV53585885; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SHD | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs1359297539, COSV73378654; called by muse, mutect2, varscan2
- SLC17A6 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV54133469; called by muse, mutect2, varscan2
- SLC25A39 | c.953G>C p.G318A (on ENST00000377095 / NM_001143780.3; = p.G310A on NM_016016.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.776); catalogued as COSV56586384; called by muse, mutect2, varscan2
- SLC2A12 | c.920C>A p.S307* | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as COSV99259629; called by muse, mutect2, varscan2
- SLC2A12 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.816); catalogued as COSV51597714; called by muse, mutect2, varscan2
- SLC4A8 | c.2511C>G p.I837M | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as rs779667166, COSV60647730, COSV60659049; called by muse, mutect2, varscan2
- SLC4A9 | c.2812G>C p.D938H (on ENST00000507527 / NM_001258428.2; = p.D914H on NM_031467.3) | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99138412; called by muse, mutect2, varscan2
- SLC5A7 | c.1738C>T p.Q580* | Nonsense Mutation (SNP) | VAF 3/30 reads (10%) | catalogued as COSV99886229; called by muse, mutect2
- SLC5A9 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52581963; called by muse, mutect2, varscan2
- SLC9B2 | c.504C>G p.I168M | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60017719; called by muse, mutect2, varscan2
- SMARCA2 | c.3737G>A p.R1246Q | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs765383428, COSV61804780; called by muse, mutect2, varscan2
- SMARCD3 | c.517G>A p.E173K (on ENST00000262188 / NM_001003801.2; = p.E160K on NM_003078.4) | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV50389010; called by muse, varscan2
- SMC1B | c.3457G>T p.E1153* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as rs1245371082, COSV100662956; called by muse, mutect2, varscan2
- SMC1B | c.1390G>T p.E464* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100662879, COSV100662957; called by muse, mutect2, varscan2
- SMG5 | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 54/269 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs753907434, COSV62433995; called by muse, mutect2, varscan2
- SMU1 | c.1125C>G p.I375M | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as COSV68139583; called by muse, mutect2, varscan2
- SNCAIP | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs773517325, COSV54402471; called by muse, mutect2, varscan2
- SNX29 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763745292, COSV60051004; called by muse, mutect2, varscan2
- SORL1 | c.3184C>T p.Q1062* | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as COSV99492851; called by muse, mutect2, varscan2
- SPAG17 | c.2983G>C p.E995Q | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV60452872, COSV60461667; called by muse, mutect2, varscan2
- SPAG6 | c.648G>C p.Q216H | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.158); catalogued as COSV57618021, COSV57618174; called by muse, mutect2, varscan2
- SPAST | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.212); catalogued as rs768241184, CM000430, CM107565, COSV59512678, COSV59514377; called by muse, mutect2, varscan2
- SPATA18 | c.648G>C p.Q216H | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV54641661; called by muse, mutect2, varscan2
- SPATS2 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV58916710; called by muse, mutect2, varscan2
- ST3GAL3 | c.290C>T p.S97L (on ENST00000361392 / NM_174964.4; = p.S82L on NM_006279.5) | Missense Mutation (SNP) | VAF 50/328 reads (15%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.997); catalogued as COSV53511130; called by muse, mutect2, varscan2
- SUPT6H | c.2515T>C p.F839L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.108); catalogued as rs1441130945, COSV58924556, COSV58925240; called by muse, mutect2, varscan2
- SVIL | c.2429C>T p.S810F (on ENST00000355867 / NM_021738.3; = p.S384F on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.83); catalogued as rs747601597, COSV63439786; called by muse, mutect2, varscan2
- SVIL | c.1985C>T p.S662L | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63439795; called by muse, mutect2, varscan2
- SYNE1 | c.2506G>T p.E836* (on ENST00000367255 / NM_182961.4; = p.E843* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | catalogued as COSV54907754, COSV99553597; called by muse, mutect2, varscan2
- TACC1 | c.386C>G p.S129C | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV52521490; called by muse, mutect2, varscan2
- TACC1 | c.1202C>G p.S401C | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as rs759126531, COSV52521507; called by muse, mutect2, varscan2
- TASOR2 | c.1474C>G p.Q492E | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV60165480, COSV60170014; called by muse, mutect2, varscan2
- TBRG4 | c.1531A>T p.S511C | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV51831803, COSV51832403; called by muse, mutect2, varscan2
- TG | c.6029G>C p.G2010A | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.378); catalogued as COSV55065252; called by muse, mutect2
- TIMELESS | c.2473G>A p.E825K | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.664); catalogued as rs748267298, COSV57508990; called by muse, mutect2
- TMCO4 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV53869174, COSV99617132; called by muse, mutect2, varscan2
- TMEM187 | c.397C>G p.L133V | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as COSV64142094; called by muse, mutect2, varscan2
- TMEM252 | c.407G>T p.G136V | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as rs1235687358, COSV66065326, COSV66065803; called by muse, mutect2, varscan2
- TMPRSS11E | c.209G>C p.R70T | Missense Mutation (SNP) | VAF 25/252 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.19); catalogued as COSV59517919; called by muse, mutect2, varscan2
- TNFRSF13B | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55426605; called by muse, mutect2, varscan2
- TNIP2 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs145021348, COSV59568834; called by muse, mutect2, varscan2
- TNKS1BP1 | c.1271T>A p.V424D | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV100835799; called by muse, mutect2, varscan2
- TOMM34 | c.604G>C p.E202Q | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0.134); catalogued as COSV65688800; called by muse, mutect2, varscan2
- TOP3B | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs779209877, COSV64116380; called by muse, mutect2, varscan2
- TP63 | c.1407G>A p.M469I | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as COSV53196509; called by muse, mutect2, varscan2
- TPH2 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 23/88 reads (26%) | catalogued as COSV61592154; called by muse, mutect2, varscan2
- TRAPPC11 | c.1939G>C p.E647Q | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.14); catalogued as COSV100591669, COSV100591997; called by muse, mutect2
- TRIM51 | c.815C>A p.A272E | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as rs1041988937, COSV55263732; called by muse, mutect2, varscan2
- TROAP | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV57743075; called by muse, mutect2, varscan2
- TSC22D1 | c.2278C>T p.P760S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV71775159; called by muse, mutect2, varscan2
- TSNAXIP1 | c.1492G>C p.E498Q | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.952); catalogued as COSV54648140; called by muse, mutect2, varscan2
- TSNAXIP1 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.701); catalogued as COSV54648148; called by muse, mutect2, varscan2
- TTN | c.51460G>C p.E17154Q (on ENST00000591111; = p.E9730Q on NM_003319.4) | Missense Mutation (SNP) | VAF 3/19 reads (16%) | PolyPhen possibly damaging (0.756); catalogued as COSV100594474; called by muse, mutect2
- TTN | c.9245C>G p.S3082C (on ENST00000591111; = p.S3036C on NM_003319.4) | Missense Mutation (SNP) | VAF 9/56 reads (16%) | PolyPhen probably damaging (0.998); catalogued as COSV59890360; called by muse, mutect2, varscan2
- UGGT1 | c.4244G>A p.S1415N | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99390247; called by muse, mutect2
- UMODL1 | c.2783G>A p.G928E (on ENST00000408910 / NM_001004416.2; = p.G1056E on NM_173568.3) | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as COSV68569275; called by muse, mutect2, varscan2
- UMPS | c.1108G>T p.E370* | Nonsense Mutation (SNP) | VAF 25/134 reads (19%) | catalogued as rs1174104527, COSV99228746; called by muse, mutect2, varscan2
- UNC13B | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs993513945, COSV65931301; called by muse, mutect2, varscan2
- UNC79 | c.6185C>G p.S2062C (on ENST00000393151 / NM_001346218.2; = p.S1885C on NM_020818.5) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs79565505, COSV56374010; called by muse, mutect2, varscan2
- UNC93B1 | c.717G>A p.M239I | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs1412333214, COSV57097823, COSV57100924; called by muse, mutect2, varscan2
- UPF2 | c.2561G>A p.R854Q | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV62658294; called by muse, mutect2, varscan2
- UQCC1 | c.695G>A p.R232K | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as COSV62901848; called by muse, mutect2, varscan2
- UROD | c.940G>C p.E314Q | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV55798999; called by muse, mutect2, varscan2
- USP16 | c.1932G>C p.E644D | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57623903; called by muse, mutect2, varscan2
- USP34 | c.2009G>A p.G670E | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.994); catalogued as rs769971844, COSV68398114; called by muse, mutect2, varscan2
- USP37 | c.147G>C p.R49S | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as COSV51441325; called by muse, mutect2, varscan2
- USP7 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 49/87 reads (56%) | SIFT tolerated (0.63); PolyPhen benign (0.066); catalogued as COSV61212944; called by muse, mutect2, varscan2
- UTP25 | c.1837C>T p.H613Y | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1419768012, COSV71965709, COSV71965729; called by muse, mutect2, varscan2
- VPS13C | c.6035C>T p.S2012L (on ENST00000644861 / NM_020821.3; = p.S1969L on NM_017684.5) | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.217); catalogued as rs745608214, COSV51121696; called by muse, mutect2, varscan2
- VPS4B | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53068457; called by muse, mutect2, varscan2
- VPS52 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); catalogued as COSV71403392; called by muse, mutect2, varscan2
- WDR35 | c.717G>A p.M239I | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as rs866797378, COSV99852773, COSV99852825; called by muse, mutect2, varscan2
- WDR74 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs767446563, COSV53677949; called by muse, mutect2
- XPR1 | c.345C>A p.F115L | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV62554526; called by muse, mutect2, varscan2
- XYLT2 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as COSV50016708, COSV99190494; called by muse, mutect2, varscan2
- YBEY | c.364C>T p.H122Y | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52448813; called by muse, mutect2, varscan2
- YEATS2 | c.138C>G p.I46M | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1156928559, COSV59361428; called by muse, mutect2, varscan2
- ZC3H13 | c.3035G>A p.G1012D | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); catalogued as COSV54447724; called by muse, mutect2, varscan2
- ZEB1 | c.3247G>A p.E1083K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV58036540, COSV58056331; called by muse, mutect2, varscan2
- ZFPM2 | c.3116G>A p.R1039Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.06); catalogued as rs779563157, COSV65872554; called by muse, mutect2, varscan2
- ZFYVE9 | c.2071G>A p.E691K | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.616); catalogued as COSV55090089, COSV99820502; called by muse, mutect2, varscan2
- ZHX3 | c.1231C>G p.P411A | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.209); catalogued as COSV58380663; called by muse, mutect2, varscan2
- ZMYM6 | c.1376C>T p.S459F | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.943); catalogued as COSV64120139; called by muse, mutect2, varscan2
- ZNF354A | c.1049G>C p.R350T | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV59982151; called by muse, mutect2, varscan2
- ZNF439 | c.1181C>T p.S394F | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.885); catalogued as COSV58308465; called by muse, mutect2, varscan2
- ZNF493 | c.727C>T p.H243Y | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV62749149; called by muse, mutect2, varscan2
- ZNF570 | c.1551G>C p.Q517H | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.322); catalogued as COSV57578056; called by muse, mutect2, varscan2
- ZNF599 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV61395520; called by muse, mutect2, varscan2
- ZNF614 | c.1398G>C p.Q466H | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.193); catalogued as COSV54544864; called by muse, mutect2, varscan2
- ZNF619 | c.1005G>C p.K335N | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59029437; called by muse, mutect2, varscan2
- ZNF7 | c.805C>T p.Q269* | Nonsense Mutation (SNP) | VAF 59/129 reads (46%) | catalogued as COSV100295645, COSV57385114; called by muse, mutect2, varscan2
- ZNF93 | c.996G>C p.K332N | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV59373948; called by muse, mutect2, varscan2
- ZNRD2 | c.241G>C p.D81H | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV57079093; called by muse, mutect2
- ZP1 | c.1159C>T p.Q387* | Nonsense Mutation (SNP) | VAF 19/122 reads (16%) | catalogued as rs1286828409, COSV53924949, COSV99612170; called by muse, mutect2, varscan2
- ZPR1 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1435947925, COSV57062225; called by muse, mutect2, varscan2
- ADTRP | c.76_77del p.Q26Gfs*24 | Frame Shift Del (DEL) | VAF 72/162 reads (44%) | called by pindel, varscan2
- ATP11B | c.3395_3396del p.S1132Cfs*13 | Frame Shift Del (DEL) | VAF 41/248 reads (17%) | called by mutect2, pindel, varscan2
- CSAG2 | c.353A>G p.K118R | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CYFIP1 | c.759G>C p.M253I | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2
- FBN2 | c.6915_6926del p.E2306_G2309del | In Frame Del (DEL) | VAF 10/22 reads (45%) | called by mutect2, pindel, varscan2
- KRT19 | c.740dup p.I248Dfs*4 | Frame Shift Ins (INS) | VAF 22/106 reads (21%) | called by mutect2, pindel, varscan2
- NAB2 | c.565_566dup p.S189Rfs*81 | Frame Shift Ins (INS) | VAF 12/31 reads (39%) | called by mutect2, pindel, varscan2
- PRAMEF14 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 51/352 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- WDR38 | c.313_316del p.Q105Gfs*24 | Frame Shift Del (DEL) | VAF 15/65 reads (23%) | called by mutect2, pindel, varscan2
- ABCA5 | c.4836C>T p.L1612= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV99287891; called by muse, mutect2
- ADCY10 | c.3288C>T p.L1096= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100896571; called by muse, mutect2
- ADGRF1 | c.1680G>A p.T560= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs369408573; called by muse, mutect2, varscan2
- ADGRG4 | c.2718G>A p.V906= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as COSV54949512; called by muse, mutect2, varscan2
- AEBP1 | c.1941C>T p.R647= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs758362244, COSV56255476; called by muse, mutect2, varscan2
- AFAP1 | c.988C>T p.L330= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs377035230; called by muse, mutect2, varscan2
- AFMID | c.894G>A p.L298= | Silent (SNP) | VAF 20/114 reads (18%) | catalogued as COSV59975392; called by muse, mutect2, varscan2
- AHDC1 | c.4491C>T p.A1497= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as rs781635710, COSV99898896; called by muse, varscan2
- AKNAD1 | c.459A>G p.S153= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV62194915; called by mutect2, varscan2
- ALG10 | c.831C>T p.G277= | Silent (SNP) | VAF 55/143 reads (38%) | catalogued as rs779882779, COSV99847919; called by muse, mutect2, varscan2
- AMER1 | c.1524C>T p.F508= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV57659044, COSV57663326; called by muse, mutect2, varscan2
- ANKLE2 | c.525C>A p.T175= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV61707810; called by muse, mutect2, varscan2
- ANKS1A | c.2952C>T p.S984= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as rs752363493, COSV64458843, COSV64459695; called by muse, mutect2, varscan2
- ATIC | c.1446G>A p.V482= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV52691870; called by muse, mutect2, varscan2
- ATP6V1A | c.1680G>A p.Q560= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as rs765616985, COSV56360969; called by muse, mutect2, varscan2
- BTN3A3 | c.36C>T p.L12= | Silent (SNP) | VAF 10/107 reads (9%) | catalogued as COSV55070906; called by muse, mutect2
- BTNL3 | c.1263C>T p.F421= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV61564349; called by muse, mutect2, varscan2
- C6orf15 | c.72C>G p.L24= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV52537257; called by muse, mutect2, varscan2
- CALCOCO2 | c.117A>G p.T39= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV51951043; called by muse, mutect2, varscan2
- CAMK4 | c.504G>A p.E168= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100000669, COSV56662312; called by muse, mutect2, varscan2
- CCDC27 | c.639C>T p.T213= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV53898403; called by muse, mutect2, varscan2
- CCT6B | c.102G>A p.L34= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs1322351152, COSV58487850; called by muse, mutect2, varscan2
- CD163L1 | c.1713G>C p.V571= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV58011068; called by muse, mutect2, varscan2
- CELSR3 | c.930G>A p.A310= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs755065079, COSV50840047; called by muse, mutect2, varscan2
- CENPT | c.1524G>A p.K508= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV54648157; called by muse, mutect2, varscan2
- CMTM1 | c.432C>T p.V144= (on ENST00000457188 / NM_181269.3; = p.V261= on NM_052999.4) | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs756055758, COSV51747901; called by muse, mutect2, varscan2
- COQ6 | c.607T>C p.L203= | Silent (SNP) | VAF 28/50 reads (56%) | catalogued as COSV53177944; called by muse, mutect2
- CSK | c.1128C>G p.L376= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as rs752992895, COSV54972563; called by muse, mutect2, varscan2
- DDX17 | c.915G>C p.L305= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV53250598; called by muse, varscan2
- DDX20 | c.621C>T p.L207= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as COSV63830768; called by muse, mutect2, varscan2
- DDX24 | c.444C>T p.V148= | Silent (SNP) | VAF 42/70 reads (60%) | catalogued as COSV58211822; called by muse, mutect2, varscan2
- DHRS3 | c.315G>A p.Q105= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV66107573; called by muse, mutect2
- DISP3 | c.1653G>A p.Q551= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV99607357; called by muse, mutect2, varscan2
- DRD5 | c.240C>T p.I80= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV100431506; called by muse, mutect2
- DSP | c.4050G>A p.K1350= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as COSV65791180; called by muse, mutect2
- DTX3L | c.2100C>T p.V700= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV56143224; called by muse, mutect2, varscan2
- DUOXA1 | c.690C>T p.L230= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as COSV50993074; called by muse, mutect2, varscan2
- EFR3A | c.2259G>A p.E753= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV54453245; called by muse, mutect2, varscan2
- ENDOV | c.553C>T p.L185= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV100108408; called by muse, mutect2
- ENGASE | c.2190C>A p.A730= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs746853950, COSV56134269; called by muse, mutect2, varscan2
- ENPP7 | c.735C>T p.S245= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as rs782431630, COSV60385373; called by muse, mutect2, varscan2
- ERBB2 | c.1129C>T p.L377= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV54072065, COSV54081722; called by muse, mutect2
- FANCI | c.402C>T p.L134= | Silent (SNP) | VAF 38/123 reads (31%) | catalogued as rs1482175099, COSV55522844; called by muse, mutect2, varscan2
- FBN3 | c.2529G>A p.G843= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV54455749; called by muse, mutect2
- FBXL2 | c.1053C>T p.C351= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as COSV52136814; called by muse, mutect2, varscan2
- FBXL3 | c.867A>G p.L289= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs982558952, COSV62918393; called by muse, mutect2, varscan2
- FECH | c.1215C>G p.L405= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV50490281; called by muse, mutect2, varscan2
- FERMT1 | c.1479G>A p.L493= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as COSV54090579; called by muse, mutect2, varscan2
- FERMT3 | c.1719C>T p.I573= (on ENST00000279227 / NM_178443.3; = p.I569= on NM_031471.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs746482825, COSV54172065; called by muse, mutect2, varscan2
- FGFR4 | c.1227C>T p.L409= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV52800866; called by muse, mutect2, varscan2
- GABBR1 | c.1828C>T p.L610= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV63540845; called by muse, mutect2, varscan2
- GNB3 | c.150G>A p.T50= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs1382910777, COSV51830958; called by muse, mutect2, varscan2
- GOLGA2 | c.96G>A p.A32= | Silent (SNP) | VAF 28/189 reads (15%) | catalogued as rs749550396, COSV60791565; called by muse, varscan2
- HADH | c.906C>T p.F302= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as rs774041111, COSV104398719, COSV58847072; called by muse, mutect2
- HSD11B1L | c.459G>A p.L153= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100028425; called by muse, mutect2
- IGF1R | c.282G>A p.E94= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV51270194, COSV51276767; called by muse, mutect2, varscan2
- IGKV1D-16 | c.81C>A p.T27= | Silent (SNP) | VAF 70/104 reads (67%) | called by muse, mutect2, varscan2
- ILF3 | c.1287C>T p.A429= | Silent (SNP) | VAF 34/46 reads (74%) | catalogued as COSV51554215; called by muse, mutect2, varscan2
- ITGAE | c.2640G>A p.L880= | Silent (SNP) | VAF 24/136 reads (18%) | catalogued as COSV53989257; called by muse, mutect2, varscan2
- KAT2B | c.282C>T p.L94= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs1407398623, COSV55426620; called by muse, mutect2, varscan2
- KDM4B | c.2019C>T p.F673= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV50208955; called by muse, mutect2, varscan2
- KLHDC3 | c.1014G>A p.L338= | Silent (SNP) | VAF 36/260 reads (14%) | catalogued as COSV55063574; called by muse, varscan2
- LARP1B | c.2316G>C p.G772= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV52794433; called by muse, mutect2, varscan2
- LGI3 | c.1068C>G p.L356= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV60442928; called by muse, mutect2, varscan2
- LTBR | c.861C>T p.F287= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as rs780363968, COSV57438247; called by muse, mutect2, varscan2
- LYST | c.801A>G p.K267= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV67703317; called by muse, mutect2, varscan2
- MAP1LC3A | c.357C>T p.F119= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs749615883, COSV54160436; called by muse, mutect2, varscan2
- MAPKBP1 | c.1935C>T p.I645= (on ENST00000456763 / NM_001128608.2; = p.I639= on NM_014994.3) | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as COSV52958203; called by muse, mutect2, varscan2
- MCHR2 | c.546G>A p.E182= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV55999591, COSV99911277; called by muse, mutect2, varscan2
- METTL7B | c.510C>G p.L170= | Silent (SNP) | VAF 23/37 reads (62%) | catalogued as COSV57691749; called by muse, mutect2, varscan2
- MORC2 | c.744T>C p.Y248= (on ENST00000397641 / NM_001303256.3; = p.Y186= on NM_014941.3) | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as COSV99309464; called by muse, mutect2, varscan2
- MPO | c.27C>T p.L9= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV56561247; called by muse, mutect2, varscan2
- MPP7 | c.324C>T p.L108= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs376512908, COSV61730099; called by muse, mutect2, varscan2
- MRPL4 | c.129C>G p.L43= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV53446635, COSV53446868; called by muse, mutect2, varscan2
- MS4A8 | c.165G>A p.S55= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as rs749352344, COSV55753093; called by muse, mutect2, varscan2
- MTMR11 | c.2100C>T p.L700= (on ENST00000439741 / NM_001145862.2; = p.L628= on NM_181873.3) | Silent (SNP) | VAF 18/154 reads (12%) | catalogued as COSV54963944; called by muse, mutect2, varscan2
- NBPF9 | c.183A>G p.E61= | Silent (SNP) | VAF 27/235 reads (11%) | called by muse, mutect2, varscan2
- NDC80 | c.1809G>A p.Q603= | Silent (SNP) | VAF 54/91 reads (59%) | catalogued as COSV55246877; called by muse, mutect2, varscan2
- NDN | c.24G>A p.L8= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100086230, COSV100086254; called by muse, mutect2, varscan2
- NLRC5 | c.54G>C p.V18= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV52649137; called by muse, mutect2, varscan2
- NOP53 | c.165G>A p.P55= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs1322029752, COSV54406766; called by mutect2, varscan2
- NRIP1 | c.3342G>A p.T1114= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as rs201612350, COSV59655097; called by muse, mutect2, varscan2
- OR51A4 | c.906G>A p.V302= | Silent (SNP) | VAF 19/126 reads (15%) | catalogued as COSV66749050; called by muse, mutect2, varscan2
- OR52A5 | c.750C>T p.V250= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs1333788333, COSV56614228; called by muse, mutect2, varscan2
- OSBPL3 | c.1059C>A p.I353= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs1192250181, COSV100513870, COSV57652722; called by muse, mutect2, varscan2
- OSBPL7 | c.2268C>T p.S756= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as rs747764207, COSV50106615; called by muse, varscan2
- PACSIN3 | c.897C>T p.F299= | Silent (SNP) | VAF 36/99 reads (36%) | catalogued as rs543891568, COSV54065140, COSV54066793; called by muse, mutect2, varscan2
- PAPOLB | c.1086C>G p.L362= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as COSV68199180; called by muse, mutect2, varscan2
- PARD3 | c.2205C>T p.L735= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV60745264; called by muse, mutect2, varscan2
- PCDHA10 | c.513C>G p.L171= | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as COSV56478108; called by muse, mutect2, varscan2
- PCDHB8 | c.546C>T p.L182= | Silent (SNP) | VAF 9/220 reads (4%) | catalogued as rs782167553, COSV99175669; called by muse, mutect2
- PCDHGA9 | c.429C>T p.N143= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as rs1022563452, COSV53899236; called by muse, mutect2, varscan2
- PCSK5 | c.1836G>A p.V612= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as rs1026038124, COSV100950343, COSV65083631; called by muse, mutect2, varscan2
- PDE11A | c.1608G>A p.G536= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs771822677, COSV53686348; called by muse, mutect2, varscan2
- PHKB | c.1860C>G p.L620= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV54514376; called by muse, mutect2, varscan2
- PHLDB1 | c.331C>A p.R111= | Silent (SNP) | VAF 25/50 reads (50%) | catalogued as rs782448370, COSV61876405, COSV61882268; called by muse, mutect2, varscan2
- PKDREJ | c.5133G>A p.L1711= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV53546494; called by muse, mutect2, varscan2
- POLL | c.912G>A p.G304= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV54573509; called by muse, mutect2, varscan2
- PRAG1 | c.3780C>T p.L1260= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV58161646; called by muse, mutect2
- PRDM7 | c.420G>A p.L140= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV57986034; called by muse, mutect2, varscan2
- PROKR2 | c.654C>T p.L218= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as COSV54085258; called by muse, mutect2, varscan2
- PRPS1L1 | c.744G>A p.L248= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as rs1258820458, COSV72649811; called by muse, mutect2, varscan2
- PRRG3 | c.351G>A p.Q117= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as COSV64850695, COSV64850711; called by muse, mutect2, varscan2
- PRUNE2 | c.7827C>G p.L2609= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV65037963; called by muse, mutect2, varscan2
- PSORS1C1 | c.51G>A p.Q17= | Silent (SNP) | VAF 14/144 reads (10%) | catalogued as COSV52535023; called by muse, varscan2
- PTAFR | c.198C>T p.F66= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV59536029; called by muse, mutect2, varscan2
- RAD54L | c.327C>G p.L109= | Silent (SNP) | VAF 14/156 reads (9%) | catalogued as COSV64335555; called by muse, mutect2
- RNF40 | c.1734G>A p.K578= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs1203661442, COSV61213657, COSV61214344; called by muse, mutect2, varscan2
- RXRA | c.477C>T p.F159= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as rs1253602601, COSV62683525; called by muse, mutect2, varscan2
- RYR1 | c.2328C>T p.F776= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV62089087; called by muse, mutect2, varscan2
- SH3RF1 | c.1650G>A p.G550= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV52918383; called by muse, mutect2, varscan2
- SLC22A4 | c.1497G>A p.L499= | Silent (SNP) | VAF 34/127 reads (27%) | catalogued as COSV52356839, COSV52359077; called by muse, mutect2, varscan2
- SLC2A12 | c.1212C>T p.L404= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV51597706; called by muse, mutect2, varscan2
- SLC30A7 | c.477C>T p.F159= | Silent (SNP) | VAF 23/131 reads (18%) | catalogued as COSV63016780; called by muse, mutect2, varscan2
- SLCO3A1 | c.324G>C p.L108= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs370591300, COSV100575848, COSV59232223, COSV59232693; called by muse, mutect2
- SMARCD3 | c.414G>A p.R138= (on ENST00000262188 / NM_001003801.2; = p.R125= on NM_003078.4) | Silent (SNP) | VAF 27/99 reads (27%) | catalogued as COSV50389012; called by muse, varscan2
- SNX8 | c.264C>T p.L88= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV56125122; called by muse, mutect2, varscan2
- SPAG1 | c.969G>C p.L323= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV52557941; called by muse, mutect2, varscan2
- SRRM2 | c.5085G>A p.P1695= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs187050172, COSV100070155, COSV57068209; called by muse, mutect2, varscan2
- TAS2R46 | c.34C>T p.L12= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs764919382, COSV67852267, COSV67862863; called by muse, mutect2, varscan2
- TBC1D4 | c.231G>A p.P77= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100884524; called by muse, mutect2
- TBC1D5 | c.2004C>T p.I668= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV53749379; called by muse, mutect2, varscan2
- TESK1 | c.453C>T p.V151= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV52410200; called by muse, mutect2
- TEX11 | c.2382G>A p.K794= (on ENST00000344304; = p.K779= on NM_031276.3) | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV60226374; called by muse, mutect2, varscan2
- TFAP2A | c.738C>G p.L246= (on ENST00000482890; = p.L238= on NM_001032280.3) | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs1290180108, COSV100116556; called by muse, mutect2
- TFB2M | c.1041G>A p.A347= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs369141918; called by muse, mutect2, varscan2
- TNR | c.3480G>C p.L1160= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs775397831, COSV54870607; called by muse, mutect2, varscan2
- TP53TG5 | c.60G>A p.E20= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV65576911; called by muse, mutect2
- TRAM1L1 | c.954C>T p.L318= | Silent (SNP) | VAF 28/141 reads (20%) | catalogued as COSV100162068, COSV60291218; called by muse, mutect2, varscan2
- TSC2 | c.2538C>T p.F846= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs1360361868, COSV54756160; ClinVar: likely benign; called by muse, mutect2, varscan2
- TSPYL6 | c.1038C>T p.V346= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as rs1473999769, COSV57811995; called by muse, mutect2, varscan2
- TTI1 | c.2985G>A p.E995= | Silent (SNP) | VAF 15/147 reads (10%) | catalogued as COSV65060492; called by muse, mutect2, varscan2
- TTN | c.42387G>A p.V14129= (on ENST00000591111; = p.V6705= on NM_003319.4) | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV59890310, COSV60005949; called by muse, mutect2, varscan2
- TTN | c.27534C>T p.F9178= (on ENST00000591111; = p.F8251= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV59890349; called by muse, mutect2, varscan2
- VWA3B | c.1437C>A p.I479= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV68240928; called by muse, mutect2, varscan2
- VWA7 | c.573C>T p.L191= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV63304201; called by muse, mutect2, varscan2
- WDR83 | c.852C>T p.A284= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV52951553; called by muse, mutect2, varscan2
- ZAN | c.972G>T p.G324= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV61805070; called by muse, mutect2, varscan2
- ZBTB39 | c.177C>T p.F59= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV55627825; called by muse, mutect2, varscan2
- ZNF440 | c.459C>T p.F153= | Silent (SNP) | VAF 32/199 reads (16%) | catalogued as rs763820178, COSV58370333; called by muse, mutect2, varscan2
- ZNF440 | c.1612C>T p.L538= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV100407485, COSV58370342; called by muse, mutect2, varscan2
- ZNF628 | c.2601C>T p.L867= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV52697907; called by muse, mutect2, varscan2
- ZNF721 | c.2526A>G p.V842= (on ENST00000338977; = p.V854= on NM_133474.4) | Silent (SNP) | VAF 38/76 reads (50%) | catalogued as COSV59089195; called by muse, mutect2, varscan2
- ZNF74 | c.1461C>G p.L487= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV62620122; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73821202 G>C | 3'Flank (SNP) | VAF 9/13 reads (69%) | called by muse, mutect2, varscan2
- BRSK2 | c.91+21039G>C | Intron (SNP) | VAF 10/17 reads (59%) | catalogued as COSV57540094; called by muse, mutect2, varscan2
- C16orf91 | c.*153G>A | 3'UTR (SNP) | VAF 8/31 reads (26%) | catalogued as COSV59949615; called by muse, mutect2, varscan2
- C3P1 | n.3449G>C | RNA (SNP) | VAF 10/60 reads (17%) | called by muse, mutect2, varscan2
- CEMIP | c.-16-31848G>A | Intron (SNP) | VAF 10/25 reads (40%) | catalogued as COSV99586072; called by muse, mutect2
- ELP5 | c.735+30G>A | Intron (SNP) | VAF 17/73 reads (23%) | catalogued as COSV63038806; called by muse, mutect2, varscan2
- FBXL13 | c.496-5601G>A | Intron (SNP) | VAF 6/29 reads (21%) | catalogued as COSV100501164; called by muse, mutect2
- FOLH1B | n.2080C>T | RNA (SNP) | VAF 24/72 reads (33%) | called by muse, mutect2, varscan2
- HDAC9 | c.2577+57T>C | Intron (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
- HIPK1 | c.3144+54C>T | Intron (SNP) | VAF 5/44 reads (11%) | catalogued as COSV61245958; called by muse, mutect2, varscan2
- MECOM | c.-121C>G | 5'UTR (SNP) | VAF 14/70 reads (20%) | catalogued as COSV52959623; called by muse, varscan2
- OR5K1 | c.*2C>G | 3'UTR (SNP) | VAF 8/26 reads (31%) | catalogued as COSV60304950; called by muse, mutect2, varscan2
- RPL23 | c.97+82G>A | Intron (SNP) | VAF 20/68 reads (29%) | catalogued as COSV99834647; called by muse, mutect2, varscan2
- SNORD116-9 | n.89G>A | RNA (SNP) | VAF 33/148 reads (22%) | called by muse, mutect2, varscan2
- UVSSA | c.*9388G>A | 3'UTR (SNP) | VAF 35/262 reads (13%) | catalogued as rs199648929, COSV61347195; called by muse, varscan2
